Somatic mutation profile of tumor specimen TCGA-21-1077-01A (aliquot TCGA-21-1077-01A-01D-1521-08) from TCGA case TCGA-21-1077, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 64.4 years (23,523 days).
Specimen TCGA-21-1077-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ffe4bf1-a2c5-40f9-b66b-d79e1b010312.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-21-1077-11A (Solid Tissue Normal), aliquot TCGA-21-1077-11A-01D-1521-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b731e1f-d9b0-434b-a7f5-ebdbcb170c55

The open-access MAF lists 245 somatic variants for this specimen: 183 protein-altering or splice-affecting, 56 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 147, Silent 56, Nonsense Mutation 19, Frame Shift Del 8, Splice Site 4, Frame Shift Ins 3, RNA 3, Splice Region 2, 3'UTR 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RHAG | c.1067+1G>A p.X356_splice | Splice Site (SNP) | VAF 45/204 reads (22%) | catalogued as rs1562012617, CS982347, COSV57703785; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 54/166 reads (33%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.3126G>A p.M1042I | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); catalogued as COSV100382816; called by muse, mutect2, varscan2
- ACSM2B | c.1615A>T p.K539* | Nonsense Mutation (SNP) | VAF 42/274 reads (15%) | catalogued as COSV61658552; called by muse, mutect2, varscan2
- ACSM4 | c.1675C>T p.L559F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV68068255; called by muse, mutect2, varscan2
- ADAMTS6 | c.2709G>A p.W903* | Nonsense Mutation (SNP) | VAF 42/308 reads (14%) | catalogued as COSV58683848, COSV58685618; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2442T>A p.C814* | Nonsense Mutation (SNP) | VAF 15/234 reads (6%) | catalogued as COSV54454818; called by muse, mutect2
- AFF3 | c.1920G>C p.E640D | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV57858936, COSV57873176; called by muse, mutect2, varscan2
- AGPAT3 | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as rs200808478, COSV52371469; called by muse, mutect2, varscan2
- ANKRD7 | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 39/176 reads (22%) | catalogued as COSV54555385; called by muse, mutect2, varscan2
- ANKS1B | c.2397A>C p.K799N | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV61358985; called by muse, mutect2, varscan2
- APBA2 | c.152T>C p.L51P | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.161); catalogued as COSV68792516; called by muse, mutect2, varscan2
- AQR | c.923A>G p.Y308C | Missense Mutation (SNP) | VAF 132/502 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV50038605; called by muse, mutect2, varscan2
- ARHGAP21 | c.4664A>G p.Q1555R | Missense Mutation (SNP) | VAF 29/279 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV57607425; called by muse, mutect2, varscan2
- ARMC2 | c.1907C>A p.T636N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.305); catalogued as COSV64551791; called by muse, mutect2, varscan2
- ATP4B | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 14/92 reads (15%) | catalogued as COSV58929242; called by muse, mutect2, varscan2
- BACH1 | c.453G>T p.Q151H | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV54519590; called by muse, mutect2
- BIRC6 | c.14171C>T p.S4724F | Missense Mutation (SNP) | VAF 44/358 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70201748; called by muse, mutect2, varscan2
- C11orf52 | c.16T>A p.C6S | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.104); catalogued as rs140110474, COSV53714831, COSV99585521; called by muse, mutect2, varscan2
- C1orf94 | c.631C>G p.L211V (on ENST00000488417 / NM_001134734.2; = p.L21V on NM_032884.5) | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV64914439; called by muse, mutect2, varscan2
- CACUL1 | c.596A>T p.Q199L | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV60995196; called by muse, mutect2
- CAMTA2 | c.1443G>T p.R481S | Missense Mutation (SNP) | VAF 91/272 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.942); catalogued as COSV61835763; called by muse, mutect2, varscan2
- CBFA2T3 | c.1088G>A p.R363Q | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs544407834, COSV51928778; called by muse, mutect2, varscan2
- CBLIF | c.280C>A p.L94I | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV57239427; called by muse, mutect2
- CCDC180 | c.3708G>C p.Q1236H | Missense Mutation (SNP) | VAF 45/297 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.824); catalogued as COSV63831735; called by muse, mutect2, varscan2
- CCDC60 | c.148A>T p.K50* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV59545983; called by muse, mutect2, varscan2
- CCDC73 | c.1015G>C p.E339Q | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV58800525; called by muse, varscan2
- CD101 | c.2134A>T p.I712F | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.541); catalogued as COSV56718983; called by muse, mutect2, varscan2
- CHRNB4 | c.77C>A p.A26E | Missense Mutation (SNP) | VAF 92/566 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.769); catalogued as rs771105669, COSV55717289, COSV99929256; called by mutect2, varscan2
- CMYA5 | c.8614C>T p.H2872Y | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as COSV71407000; called by muse, mutect2
- CNTN3 | c.1172A>G p.K391R | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV55175682, COSV55185054; called by muse, mutect2, varscan2
- CNTN3 | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.696); catalogued as COSV55163859; called by muse, mutect2
- COL7A1 | c.6393+1G>A p.X2131_splice | Splice Site (SNP) | VAF 63/200 reads (32%) | catalogued as COSV60395896, COSV60397362; called by muse, mutect2, varscan2
- CPS1 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 56/337 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV51814548; called by muse, mutect2, varscan2
- CTNNA3 | c.2401-2A>G p.X801_splice | Splice Site (SNP) | VAF 21/167 reads (13%) | catalogued as COSV101041287; called by muse, mutect2, varscan2
- CTNNB1 | c.2141C>G p.P714R | Missense Mutation (SNP) | VAF 62/233 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.209); catalogued as COSV100846291, COSV62705613; called by muse, mutect2, varscan2
- CYP11B1 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as rs1193417504, COSV52828390; called by muse, mutect2, varscan2
- DDX58 | c.76C>A p.L26M | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV65883683; called by muse, mutect2, varscan2
- DGKZ | c.749G>C p.G250A (on ENST00000454345 / NM_001105540.2; = p.G61A on NM_003646.4) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV58990637; called by muse, mutect2, varscan2
- DIAPH1 | c.2474-2A>T p.X825_splice | Splice Site (SNP) | VAF 33/152 reads (22%) | catalogued as COSV99526085; called by muse, mutect2, varscan2
- DNMT1 | c.2507A>T p.Y836F | Missense Mutation (SNP) | VAF 220/648 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.082); catalogued as COSV61580650; called by muse, varscan2
- EIF6 | c.65C>T p.T22I | Missense Mutation (SNP) | VAF 68/286 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV65583526; called by muse, mutect2, varscan2
- EPHA3 | c.205del p.Q69Rfs*14 | Frame Shift Del (DEL) | VAF 14/123 reads (11%) | catalogued as COSV60703506; called by mutect2, varscan2
- ESAM | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as COSV54035557; called by muse, mutect2, varscan2
- F13A1 | c.1808C>G p.A603G | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV53561205; called by muse, mutect2, varscan2
- FAM135B | c.2051C>G p.S684C | Missense Mutation (SNP) | VAF 28/196 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52734599, COSV52752032; called by muse, mutect2, varscan2
- FBXL7 | c.1426C>T p.R476C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1275721257, COSV61648197; called by muse, mutect2, varscan2
- FNBP4 | c.2753C>T p.P918L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.261); catalogued as COSV55449804; called by muse, mutect2, varscan2
- FNIP1 | c.1120A>G p.M374V | Missense Mutation (SNP) | VAF 47/180 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.171); catalogued as rs551838274, COSV57197745; called by muse, mutect2, varscan2
- FOXI1 | c.718G>T p.V240L | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV60389013; called by muse, mutect2, varscan2
- FOXR2 | c.298G>A p.G100R | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs774657036, COSV59258953; called by muse, mutect2, varscan2
- GATA3 | c.1304C>G p.P435R | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV60520066; called by muse, mutect2, varscan2
- GDF2 | c.627C>A p.S209R | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as rs374479283; called by muse, mutect2, varscan2
- GEN1 | c.2590G>T p.E864* | Nonsense Mutation (SNP) | VAF 16/152 reads (11%) | catalogued as COSV58057270; called by muse, mutect2
- GFRAL | c.682C>A p.Q228K | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV61230166, COSV61232343; called by muse, mutect2, varscan2
- GJA5 | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 18/138 reads (13%) | catalogued as rs1476854402, COSV54784896; called by muse, mutect2, varscan2
- GPRIN1 | c.145C>G p.Q49E | Missense Mutation (SNP) | VAF 61/281 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as COSV56140877, COSV99992254; called by muse, mutect2, varscan2
- GRIN3A | c.2371G>T p.G791* | Nonsense Mutation (SNP) | VAF 10/145 reads (7%) | catalogued as COSV62455498; called by muse, mutect2
- GRM6 | c.1830C>A p.Y610* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV51444642; called by muse, mutect2, varscan2
- GTF2H4 | c.17C>A p.S6* | Nonsense Mutation (SNP) | VAF 19/154 reads (12%) | catalogued as COSV52559653; called by muse, mutect2, varscan2
- HCN3 | c.1168C>T p.H390Y | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as COSV64234464; called by muse, mutect2, varscan2
- HERC2 | c.2391G>A p.M797I | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1418394073, COSV55321077, COSV55330970; called by muse, mutect2
- HIGD1A | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.651); catalogued as COSV58415126; called by muse, mutect2, varscan2
- IGLV6-57 | c.292T>A p.S98T | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.035); catalogued as COSV66504160; called by muse, mutect2, varscan2
- ITGA8 | c.389T>A p.F130Y | Missense Mutation (SNP) | VAF 69/366 reads (19%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); catalogued as COSV65231066; called by muse, mutect2, varscan2
- ITGB8 | c.1383T>G p.I461M | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV56010553; called by muse, mutect2
- KCNJ3 | c.969G>T p.W323C | Missense Mutation (SNP) | VAF 18/225 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99715439; called by muse, mutect2
- KRT72 | c.1457G>C p.G486A | Missense Mutation (SNP) | VAF 67/375 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV53374978; called by muse, mutect2, varscan2
- LCP1 | c.487del p.L163Ffs*4 | Frame Shift Del (DEL) | VAF 54/329 reads (16%) | catalogued as COSV59941524; called by mutect2, pindel, varscan2
- LCT | c.2219C>T p.S740F | Missense Mutation (SNP) | VAF 37/217 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.202); catalogued as rs753715951, COSV51552283; called by muse, mutect2, varscan2
- LGALS3BP | c.1670C>T p.S557F | Missense Mutation (SNP) | VAF 22/181 reads (12%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.99); catalogued as rs973119032, COSV53165152; called by muse, mutect2, varscan2
- LPIN2 | c.1175A>G p.H392R | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV55240965; called by muse, mutect2, varscan2
- LUC7L3 | c.79G>T p.V27L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.991); catalogued as COSV53587817; called by muse, mutect2, varscan2
- MARCHF6 | c.1874G>T p.R625L | Missense Mutation (SNP) | VAF 45/211 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV56883219; called by muse, mutect2, varscan2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2
- MEIOB | c.1268C>T p.S423L | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs771416758, COSV58054616; called by muse, mutect2, varscan2
- MIDEAS | c.2612A>T p.Y871F | Missense Mutation (SNP) | VAF 180/553 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54095882; called by muse, mutect2, varscan2
- MRC2 | c.2020G>T p.A674S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1219418786, COSV57641306; called by muse, mutect2, varscan2
- MYH10 | c.326A>G p.Y109C | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52604383; called by muse, mutect2, varscan2
- MYH7B | c.1355A>C p.N452T | Missense Mutation (SNP) | VAF 50/337 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV53421709; called by muse, mutect2, varscan2
- NAIF1 | c.81G>C p.K27N | Missense Mutation (SNP) | VAF 87/437 reads (20%) | SIFT tolerated (0.96); PolyPhen benign (0.028); catalogued as COSV66091315; called by muse, mutect2, varscan2
- NEB | c.4342G>A p.G1448R | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200002537, COSV51429406; called by muse, mutect2, varscan2
- NR1H4 | c.886G>C p.E296Q (on ENST00000551379 / NM_001206993.2; = p.E282Q on NM_005123.4) | Missense Mutation (SNP) | VAF 29/390 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.098); catalogued as COSV51853452, COSV99500827; called by muse, mutect2
- NUAK1 | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs557272627, COSV54604706; called by muse, mutect2, varscan2
- NUP188 | c.972G>T p.L324F | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65363096; called by muse, mutect2, varscan2
- NUTM2G | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 36/228 reads (16%) | catalogued as COSV63617458; called by muse, varscan2
- NUTM2G | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 39/246 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.381); catalogued as COSV63617463; called by muse, varscan2
- OLFM3 | c.80C>A p.P27Q | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV58800407; called by muse, mutect2, varscan2
- ONECUT1 | c.1090G>T p.A364S | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.686); catalogued as COSV59949585; called by muse, mutect2, varscan2
- OR2B11 | c.185C>A p.P62H | Missense Mutation (SNP) | VAF 146/322 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100275756, COSV100276452, COSV59510571; called by muse, mutect2, varscan2
- OR51B2 | c.838C>A p.L280I | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.654); catalogued as COSV60917032; called by muse, mutect2, varscan2
- OR5L1 | c.732C>A p.H244Q | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs145975508; called by muse, mutect2
- OR5L1 | c.733C>A p.L245I | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs770995985, COSV61734405; called by muse, mutect2
- OR8G5 | c.495G>T p.R165S | Missense Mutation (SNP) | VAF 95/500 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.472); catalogued as rs1307402693, COSV100422296, COSV100422531; called by muse, mutect2, varscan2
- PARP11 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 36/222 reads (16%) | catalogued as COSV57395798; called by muse, mutect2, varscan2
- PATJ | c.109A>G p.M37V | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs564523661, COSV57165329; called by muse, mutect2, varscan2
- PCDH15 | c.3580G>T p.G1194* | Nonsense Mutation (SNP) | VAF 27/245 reads (11%) | catalogued as COSV57316728, COSV57342928; called by muse, mutect2, varscan2
- PCDH17 | c.1513G>A p.G505S | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV64975625; called by muse, mutect2, varscan2
- PCDHA7 | c.1928C>A p.P643Q | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.433); catalogued as COSV100971316, COSV65348236; called by muse, mutect2
- PCDHB12 | c.1402C>A p.L468M | Missense Mutation (SNP) | VAF 59/240 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV99506983; called by muse, mutect2, varscan2
- PDXDC1 | c.528A>G p.I176M | Missense Mutation (SNP) | VAF 32/356 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs1355362811, COSV57908633; called by muse, mutect2
- PHEX | c.277C>G p.P93A | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.966); catalogued as COSV65076601; called by muse, mutect2, varscan2
- PI16 | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs773601220, COSV65448010, COSV65448349; called by muse, mutect2, varscan2
- POLR3E | c.838G>C p.D280H | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55401592; called by muse, mutect2, varscan2
- PPARGC1B | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as rs745645815, COSV58530645; called by muse, mutect2, varscan2
- PPP1R16A | c.1310G>A p.S437N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1429303538, COSV52953652; called by muse, mutect2, varscan2
- PROX1 | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 42/122 reads (34%) | catalogued as COSV54780655; called by muse, mutect2, varscan2
- PSMD11 | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as COSV55577141, COSV99912371; called by muse, mutect2
- RELN | c.6871C>T p.L2291F | Missense Mutation (SNP) | VAF 66/233 reads (28%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.466); catalogued as COSV59003702, COSV59010623; called by muse, mutect2, varscan2
- RELN | c.3286C>G p.Q1096E | Missense Mutation (SNP) | VAF 38/293 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV58996045; called by muse, mutect2, varscan2
- RELN | c.1296T>G p.D432E | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV59012486; called by muse, mutect2, varscan2
- RGL1 | c.972T>G p.N324K (on ENST00000360851 / NM_001297672.2; = p.N359K on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/694 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58988381; called by muse, mutect2
- ROBO3 | c.3296G>T p.G1099V | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.368); catalogued as rs1347678858, COSV67301263; called by muse, mutect2, varscan2
- ROCK1 | c.3299C>G p.S1100C | Missense Mutation (SNP) | VAF 33/233 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV101296620, COSV67696837; called by muse, mutect2, varscan2
- RTP5 | c.849C>A p.F283L | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.125); catalogued as COSV58320748; called by muse, mutect2, varscan2
- RTTN | c.1918G>T p.E640* | Nonsense Mutation (SNP) | VAF 16/75 reads (21%) | catalogued as COSV55347433; called by muse, mutect2, varscan2
- RYR2 | c.5174A>T p.Y1725F | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV63693758; called by muse, varscan2
- SCAPER | c.1798C>T p.H600Y | Missense Mutation (SNP) | VAF 71/478 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV57743556; called by muse, mutect2, varscan2
- SENP2 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 29/602 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as rs756783643, COSV56195312; called by muse, mutect2
- SEPTIN5 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs776341079, COSV63530769; called by muse, mutect2, varscan2
- SERF2 | c.116G>T p.R39M | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV51049900; called by muse, mutect2, varscan2
- SHLD1 | c.164C>G p.S55C | Missense Mutation (SNP) | VAF 37/289 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV57437445; called by muse, mutect2, varscan2
- SLC16A10 | c.556C>A p.P186T | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64354711; called by muse, mutect2, varscan2
- SLC25A36 | c.651A>C p.E217D | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs772045480, COSV60782349; called by muse, mutect2, varscan2
- SLC45A2 | c.290C>G p.S97C | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as COSV56872959; called by muse, mutect2, varscan2
- SLCO6A1 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 81/542 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as rs1267598371, COSV65805369; called by muse, mutect2, varscan2
- SLITRK3 | c.675G>A p.M225I | Missense Mutation (SNP) | VAF 21/451 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV53849448; called by muse, mutect2
- SNAP91 | c.766C>A p.Q256K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as COSV52126234; called by muse, mutect2
- SOS1 | c.1772A>G p.N591S | Missense Mutation (SNP) | VAF 33/308 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.041); catalogued as rs757213444, COSV67676173; ClinVar: benign; called by muse, mutect2, varscan2
- SPATA31D1 | c.798G>T p.L266F | Missense Mutation (SNP) | VAF 69/657 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV61197696; called by muse, mutect2, varscan2
- SPHKAP | c.3182C>T p.A1061V | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs778910801, COSV60869051; called by muse, mutect2, varscan2
- SPTBN1 | c.6722A>C p.K2241T | Missense Mutation (SNP) | VAF 69/511 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61690069; called by muse, mutect2, varscan2
- STIP1 | c.1196A>G p.N399S | Missense Mutation (SNP) | VAF 154/505 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780822146, COSV59439160; called by muse, mutect2, varscan2
- STRBP | c.761G>A p.C254Y | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as COSV62118793; called by muse, mutect2, varscan2
- SYNE1 | c.22594G>C p.E7532Q (on ENST00000367255 / NM_182961.4; = p.E7461Q on NM_033071.3) | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV55020484, COSV55051805; called by muse, mutect2, varscan2
- TDRD6 | c.970G>T p.G324* | Nonsense Mutation (SNP) | VAF 32/118 reads (27%) | catalogued as COSV60176607; called by muse, mutect2, varscan2
- TECTA | c.5453G>T p.C1818F | Missense Mutation (SNP) | VAF 15/246 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50732407; called by muse, mutect2
- TELO2 | c.493G>T p.D165Y | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51979194; called by muse, mutect2
- TENM4 | c.7091G>T p.G2364V | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53640776; called by muse, mutect2, varscan2
- TFB1M | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 43/262 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.013); catalogued as COSV51641827; called by muse, mutect2, varscan2
- THOC3 | c.779G>T p.R260L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV99442003, COSV99442041; called by mutect2, varscan2
- TMCC3 | c.716A>T p.Y239F | Missense Mutation (SNP) | VAF 55/246 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.446); catalogued as rs762511692, COSV54155338; called by muse, mutect2, varscan2
- TMEM145 | c.1445G>T p.R482L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs1467739554, COSV52090596, COSV52095927; called by muse, mutect2, varscan2
- TOR1B | c.932T>C p.M311T | Missense Mutation (SNP) | VAF 34/202 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs201490031, COSV52213736; called by muse, mutect2, varscan2
- TPK1 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 74/576 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as COSV63642838; called by muse, mutect2, varscan2
- TRANK1 | c.4130T>G p.L1377R | Missense Mutation (SNP) | VAF 108/370 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57154511; called by muse, varscan2
- TRANK1 | c.2483C>T p.T828I | Missense Mutation (SNP) | VAF 36/221 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.928); catalogued as COSV57154533; called by muse, mutect2, varscan2
- TRIM42 | c.1722C>A p.Y574* | Nonsense Mutation (SNP) | VAF 29/224 reads (13%) | catalogued as COSV53884263; called by muse, mutect2, varscan2
- TRPC4 | c.220C>A p.L74I | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58996418, COSV59005054; called by muse, mutect2, varscan2
- TSHZ3 | c.3005G>T p.R1002L | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV53684808, COSV99550988; called by muse, mutect2, varscan2
- TSKS | c.1712G>A p.G571E | Missense Mutation (SNP) | VAF 74/249 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.79); catalogued as rs868763430, COSV55876225; called by muse, mutect2, varscan2
- TTC21B | c.802A>T p.T268S | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54632053; called by muse, mutect2, varscan2
- TUFM | c.851G>C p.R284P | Missense Mutation (SNP) | VAF 38/311 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV57948554, COSV57949231; called by muse, mutect2, varscan2
- TXLNB | c.1775G>A p.G592D | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.006); catalogued as COSV64444582; called by muse, mutect2, varscan2
- USH2A | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 78/246 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100240574, COSV56390686; called by muse, mutect2, varscan2
- USP13 | c.1844G>T p.R615L | Missense Mutation (SNP) | VAF 49/1083 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55867131; called by muse, mutect2
- USP54 | c.1159A>G p.I387V | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV60444227; called by muse, mutect2, varscan2
- UTP14C | c.1741G>C p.E581Q | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as COSV73000719; called by muse, mutect2, varscan2
- UTRN | c.2527C>A p.R843= | Splice Region (SNP) | VAF 18/93 reads (19%) | catalogued as COSV62339448; called by muse, mutect2, varscan2
- WDR33 | c.3664G>A p.G1222S | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.998); catalogued as COSV59251436; called by muse, mutect2, varscan2
- ZC3H12B | c.1627C>A p.H543N | Missense Mutation (SNP) | VAF 48/100 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.272); catalogued as COSV59049406; called by muse, mutect2, varscan2
- ZCCHC14 | c.2741C>G p.T914S (on ENST00000268616; = p.T1051S on NM_015144.3) | Missense Mutation (SNP) | VAF 66/362 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV51887543; called by muse, mutect2, varscan2
- ZFY | c.466A>T p.S156C | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.591); catalogued as COSV50083590; called by muse, mutect2, varscan2
- ZIC1 | c.635C>A p.A212D | Missense Mutation (SNP) | VAF 106/182 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs752213758, COSV51555196; called by muse, mutect2, varscan2
- ZMYM1 | c.2250G>T p.L750F | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV63252334; called by muse, mutect2, varscan2
- ZNF257 | c.1393G>T p.G465C | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV71306197; called by muse, mutect2, varscan2
- ZNF444 | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV61363630; called by muse, mutect2, varscan2
- ZNF462 | c.7017C>A p.H2339Q | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV52943608; called by muse, mutect2
- ZNF692 | c.125A>G p.K42R | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs760655992, COSV60659731; called by muse, mutect2, varscan2
- ZSCAN18 | c.392T>C p.L131P | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV53734310; called by muse, mutect2, varscan2
- ZSCAN5B | c.1390G>T p.E464* | Nonsense Mutation (SNP) | VAF 20/94 reads (21%) | catalogued as COSV62000486; called by muse, mutect2, varscan2
- ZSCAN5B | c.776A>G p.K259R | Missense Mutation (SNP) | VAF 41/235 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.265); catalogued as COSV62000491; called by muse, mutect2, varscan2
- AL592490.1 | c.2123_2127del p.Y708Ffs*4 | Frame Shift Del (DEL) | VAF 57/381 reads (15%) | called by mutect2, pindel, varscan2
- C12orf4 | c.677G>T p.W226L | Missense Mutation (SNP) | VAF 36/251 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- DNAJB5 | c.873del p.C292Afs*10 | Frame Shift Del (DEL) | VAF 48/452 reads (11%) | called by mutect2, pindel, varscan2
- GIN1 | c.909dup p.E304* | Frame Shift Ins (INS) | VAF 39/303 reads (13%) | called by mutect2, pindel, varscan2
- HP | c.1032del p.K345Sfs*31 | Frame Shift Del (DEL) | VAF 28/196 reads (14%) | called by mutect2, varscan2
- IGKV1-6 | c.85T>A p.S29T | Missense Mutation (SNP) | VAF 50/416 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PCSK2 | c.323dup p.R109Afs*8 | Frame Shift Ins (INS) | VAF 28/142 reads (20%) | called by mutect2, pindel, varscan2
- SIDT1 | c.2474del p.P825Lfs*41 | Frame Shift Del (DEL) | VAF 18/192 reads (9%) | called by mutect2, pindel
- SOX10 | c.666del p.M223Cfs*63 | Frame Shift Del (DEL) | VAF 23/145 reads (16%) | called by mutect2, pindel, varscan2
- UGT2B15 | c.861dup p.P288Tfs*4 | Frame Shift Ins (INS) | VAF 66/438 reads (15%) | called by mutect2, varscan2
- ZCCHC12 | c.819del p.D274Mfs*4 | Frame Shift Del (DEL) | VAF 71/163 reads (44%) | called by mutect2, pindel, varscan2
- ACTN2 | c.744C>T p.Y248= | Silent (SNP) | VAF 64/149 reads (43%) | catalogued as rs749565466, COSV63976171, COSV63976770; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARAP2 | c.4692G>C p.L1564= | Silent (SNP) | VAF 36/209 reads (17%) | catalogued as COSV58288515; called by muse, mutect2, varscan2
- ASB17 | c.453C>A p.L151= | Silent (SNP) | VAF 35/95 reads (37%) | catalogued as COSV52410924; called by muse, mutect2, varscan2
- ATP13A4 | c.1197C>T p.I399= | Silent (SNP) | VAF 112/812 reads (14%) | catalogued as COSV55069135; called by muse, mutect2, varscan2
- BAZ2B | c.558A>G p.T186= | Silent (SNP) | VAF 46/228 reads (20%) | catalogued as COSV58603975; called by muse, mutect2
- CBLIF | c.279C>G p.G93= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as COSV57239436; called by muse, mutect2
- CDC40 | c.1044C>T p.L348= | Silent (SNP) | VAF 31/152 reads (20%) | catalogued as rs1448595846, COSV57009907; called by muse, mutect2, varscan2
- CDIN1 | c.735C>T p.V245= (on ENST00000437989; = p.V147= on NM_032499.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/229 reads (7%) | catalogued as COSV57712592; called by muse, mutect2
- CUBN | c.5112T>A p.P1704= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as COSV64719466; called by muse, mutect2, varscan2
- DDX53 | c.894G>T p.G298= | Silent (SNP) | VAF 53/133 reads (40%) | catalogued as COSV60069481; called by muse, mutect2, varscan2
- FANK1 | c.240G>C p.L80= | Silent (SNP) | VAF 60/356 reads (17%) | catalogued as COSV64156746; called by muse, mutect2, varscan2
- FMNL1 | c.1980C>T p.F660= | Silent (SNP) | VAF 55/188 reads (29%) | catalogued as rs1168183383, COSV58957606; called by muse, mutect2, varscan2
- GARRE1 | c.123G>C p.L41= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV55100031, COSV55100853, COSV55100888; called by muse, mutect2, varscan2
- HADHB | c.501G>A p.L167= | Silent (SNP) | VAF 21/188 reads (11%) | catalogued as COSV58546971; called by muse, mutect2, varscan2
- HEATR9 | c.585G>A p.E195= | Silent (SNP) | VAF 39/264 reads (15%) | catalogued as rs1212026467; called by muse, mutect2, varscan2
- HPX | c.867G>T p.R289= | Silent (SNP) | VAF 39/297 reads (13%) | catalogued as COSV56419823; called by muse, mutect2, varscan2
- HSPD1 | c.631T>C p.L211= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as COSV61444967; called by muse, mutect2, varscan2
- HTR1A | c.531C>T p.T177= | Silent (SNP) | VAF 64/396 reads (16%) | catalogued as COSV60500294, COSV60501450; called by muse, mutect2, varscan2
- KLHL24 | c.591T>C p.D197= | Silent (SNP) | VAF 36/830 reads (4%) | catalogued as COSV54427072; called by muse, mutect2
- LIPI | c.1425A>C p.T475= | Silent (SNP) | VAF 37/281 reads (13%) | catalogued as COSV60712990; called by muse, mutect2, varscan2
- LRFN2 | c.1299C>T p.T433= | Silent (SNP) | VAF 31/185 reads (17%) | catalogued as COSV57829574; called by muse, mutect2, varscan2
- MACF1 | c.4062G>A p.L1354= | Silent (SNP) | VAF 25/199 reads (13%) | catalogued as COSV58382332; called by muse, mutect2, varscan2
- MBTPS1 | c.2613G>A p.S871= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs770241979, COSV58571414; called by muse, varscan2
- METTL3 | c.1146C>T p.D382= | Silent (SNP) | VAF 29/209 reads (14%) | catalogued as rs758697624, COSV52969841; called by muse, mutect2, varscan2
- MGAT3 | c.606G>A p.R202= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV57866381; called by muse, mutect2, varscan2
- MGAT5 | c.120T>G p.P40= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV56097859; called by muse, mutect2, varscan2
- MINAR1 | c.2469G>A p.V823= | Silent (SNP) | VAF 71/248 reads (29%) | catalogued as COSV59584109; called by muse, mutect2, varscan2
- MTRF1 | c.117G>T p.L39= | Silent (SNP) | VAF 40/258 reads (16%) | catalogued as COSV53481715; called by muse, mutect2, varscan2
- MUC4 | c.15363C>A p.S5121= (on ENST00000463781 / NM_018406.7; = p.S885= on NM_004532.6) | Silent (SNP) | VAF 27/478 reads (6%) | catalogued as COSV57787925; called by muse, mutect2
- MYO3A | c.1180C>T p.L394= | Silent (SNP) | VAF 13/130 reads (10%) | catalogued as rs570749940, COSV56333286, COSV56336558; called by muse, mutect2, varscan2
- NBAS | c.4650C>A p.A1550= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV55727025; called by muse, mutect2, varscan2
- NEB | c.6681G>A p.Q2227= | Silent (SNP) | VAF 37/269 reads (14%) | catalogued as COSV51429389; called by muse, mutect2, varscan2
- NPAS4 | c.1260T>C p.L420= | Silent (SNP) | VAF 54/394 reads (14%) | catalogued as rs1250458096, COSV60651166; called by muse, mutect2, varscan2
- OR2B11 | c.186C>A p.P62= | Silent (SNP) | VAF 148/326 reads (45%) | catalogued as COSV59509548, COSV59510563; called by muse, mutect2, varscan2
- OR56B1 | c.351G>T p.V117= | Silent (SNP) | VAF 37/117 reads (32%) | catalogued as rs760456044, COSV57723372; called by muse, mutect2, varscan2
- PCDHB13 | c.540G>T p.R180= | Silent (SNP) | VAF 36/220 reads (16%) | catalogued as COSV53398032; called by muse, mutect2, varscan2
- PDE1C | c.1338C>A p.T446= | Silent (SNP) | VAF 93/293 reads (32%) | catalogued as COSV58518114; called by muse, mutect2, varscan2
- PDYN | c.648C>A p.P216= | Silent (SNP) | VAF 80/344 reads (23%) | catalogued as COSV54102307; called by muse, mutect2, varscan2
- PHLDB2 | c.3295A>C p.R1099= (on ENST00000393925 / NM_001134439.2; = p.R1056= on NM_145753.2) | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as COSV67312899; called by muse, mutect2, varscan2
- PHLPP1 | c.2601A>G p.L867= | Silent (SNP) | VAF 36/295 reads (12%) | catalogued as COSV53031732; called by muse, mutect2, varscan2
- PLRG1 | c.894G>T p.P298= | Silent (SNP) | VAF 40/180 reads (22%) | catalogued as COSV57423275, COSV57423963; called by muse, mutect2, varscan2
- PLXNB2 | c.2061C>T p.F687= | Silent (SNP) | VAF 21/246 reads (9%) | catalogued as COSV63782693; called by muse, mutect2
- PTPRB | c.2529T>C p.N843= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as rs1414515778, COSV54244785; called by muse, mutect2, varscan2
- PXDNL | c.2028G>A p.V676= | Silent (SNP) | VAF 19/38 reads (50%) | catalogued as COSV62491290; called by muse, mutect2, varscan2
- RTP5 | c.603C>T p.V201= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV58320737; called by muse, mutect2, varscan2
- SHANK2 | c.3438G>T p.P1146= | Silent (SNP) | VAF 20/142 reads (14%) | catalogued as COSV53604922; called by muse, mutect2, varscan2
- SLC16A10 | c.555G>A p.Q185= | Silent (SNP) | VAF 26/173 reads (15%) | catalogued as COSV64354696; called by muse, mutect2, varscan2
- SNTB1 | c.186C>A p.T62= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV101179915; called by muse, mutect2, varscan2
- SOX1 | c.273C>A p.V91= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV58379524; called by muse, mutect2, varscan2
- ST8SIA3 | c.202C>T p.L68= | Silent (SNP) | VAF 53/356 reads (15%) | catalogued as COSV104407574, COSV60654515; called by muse, mutect2, varscan2
- TBC1D4 | c.1413C>G p.L471= | Silent (SNP) | VAF 15/128 reads (12%) | catalogued as COSV66489938; called by muse, mutect2, varscan2
- TMEM267 | c.534C>T p.F178= | Silent (SNP) | VAF 69/246 reads (28%) | catalogued as COSV67992881; called by muse, mutect2, varscan2
- TNR | c.4041C>T p.L1347= | Silent (SNP) | VAF 30/358 reads (8%) | catalogued as COSV54894979; called by muse, mutect2
- TPRG1 | c.297G>A p.L99= | Silent (SNP) | VAF 133/289 reads (46%) | catalogued as rs780355022, COSV61466014; called by muse, mutect2, varscan2
- TTN | c.12213A>T p.P4071= (on ENST00000591111; = p.P4025= on NM_003319.4) | Silent (SNP) | VAF 23/163 reads (14%) | catalogued as COSV60153447; called by muse, mutect2, varscan2
- USP7 | c.2655C>T p.I885= | Silent (SNP) | VAF 57/320 reads (18%) | catalogued as COSV61215600; called by muse, mutect2, varscan2
- ANKRD20A5P | n.162G>T | RNA (SNP) | VAF 13/47 reads (28%) | called by muse, mutect2, varscan2
- DDX41 | c.*556G>T | 3'UTR (SNP) | VAF 96/374 reads (26%) | catalogued as COSV57252178, COSV57253026; called by muse, mutect2, varscan2
- NR4A3 | c.1254+194C>G | Intron (SNP) | VAF 9/78 reads (12%) | catalogued as COSV100432238; called by muse, mutect2
- RN7SL106P | chr15:23163095 C>T | 5'Flank (SNP) | VAF 40/498 reads (8%) | called by muse, varscan2
- SSPOP | n.1009A>G | RNA (SNP) | VAF 26/88 reads (30%) | catalogued as COSV50488081; called by muse, mutect2, varscan2
- ZNF658B | n.868C>T | RNA (SNP) | VAF 98/636 reads (15%) | catalogued as rs1346303579; called by muse, mutect2, varscan2
